Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A9WK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A9WK-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

NOT REPORTED

TUMOR LOCATION

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

POSTERIOR

RIGHT

LEFT

SEMINAL VESICAL INVASION

PRESENT

BOTH

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

POSTERIOR

RIGHT

LEFT

NATURE OF POSITIVE MARGINS

NOT REPORTED

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

MILLIMETRIC EXTENT OF POSITIVE MARGINS: _NOT REPORTED

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

NOT REPORTED

LYMPHOVASCULAR INVASION

ABSENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: _30%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

LEFT PELVIC

NUMBER OF NODES IDENTIFIED: _1_

NUMBER OF NODES INVOLVED BY METASTASIS: _0_

ADDITIONAL PATHOLOGIC FINDINGS

HIGH-GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA

BASAL CELL HYPERPLASIA

ATROPHY

ICD-0-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

JW 5/19/14

[page 2 of 2]
PATHOLOGICAL STAGING

pT3b
pN0
pMX

Source: NCI Genomic Data Commons file 10c11fa0-bad2-44ab-8cd3-5c3885e9e8d1 (TCGA-YL-A9WK.B963A02D-0AE8-494C-A522-376AFABA374A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).